TCGA case TCGA-B0-4811 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/57578a0d-b719-46e7-83ab-872a4e984dbb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Dead; Days to death: 1,417 days (3.9 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 48.7 years (17,792 days); Year of diagnosis: 2001; AJCC staging edition: 5th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 3.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 50.0 years (18,250 days); Days to diagnosis: 458 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 458 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,417 days (3.9 years); Disease response: With Tumor.

Molecular and laboratory tests
- Hemoglobin: Normal.
- Calcium: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B0-4811-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1.4; Shortest dimension: 0.1.
  Slide TCGA-B0-4811-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-B0-4811-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-B0-4811-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B0-4811-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 0.9; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes.
- Follow-up form: Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery days to met: 425.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,417 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,417 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 458 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B0-4811-01A-01D-1499-01): tumor purity 0.35, ploidy 4.42, whole-genome doublings 2.
